CCDI case PBBIMT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/689850c2-44ec-4a4e-89e1-6c439ab0ba69

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.8 years (6,146 days).

Biospecimens (3 samples)
- Sample 0D9JN3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9JN5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9JN7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
